Surgical pathology report (de-identified scan), TCGA case TCGA-XM-A8R9, project TCGA-THYM (Thymoma), tissue source site MSKCC, specimen TCGA-XM-A8R9-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account #: [REDACTED] Date of Procedure: [REDACTED]
[REDACTED] (Age: F Date of Receipt: [REDACTED]
Physician: [REDACTED] Date of Report: [REDACTED]
CC: [REDACTED]
Patient Address: [REDACTED]

....

Clinical Diagnosis & History:
year old female with incidental anterior mediastinal mass, Clinically
Stage II thymoma.

Specimens Submitted:
1: SP: Anterior mediastinal mass for tissue (fs)

DIAGNOSIS:

1. ANTERIOR MEDIASTINUM, MASS; EXCISION (FS):
- THYMOMA, 2004 WHO TYPE A AND MICRONODULAR THYMOMA WITH LYMPHOID STROMA (SEE NOTE).
- TUMOR SIZE: 10 X 6 X 4.2 CM.
- THERE IS EXTENSIVE NECROSIS.
- THERE IS NO THYMIC CAPSULAR INVASION.
- THE INKED MARGIN IS FREE OF TUMOR.

NOTE: THE TUMOR IS COMPOSED OF TWO COMPONENTS: 1) TYPE A THYMOMA CONSISTING OF EPITHELIAL NODULES COMPOSED OF BLAND SPINDLE CELLS, AND 2) MICRONODULAR THYMOMA CONSISTING OF LYMPHOCYTE-RICH AREAS WITH EPITHELIAL MICRONODULES BUT WITHOUT ADMIXED EPITHELIAL TUMOR CELLS. IMMUNOHISTOCHEMICAL STAINING SHOWS THE EPITHELIAL CELLS ARE POSITIVE FOR AE1:AE3 BUT NEGATIVE FOR CD5. THE LYMPHOCYTES ARE PREDOMINANTLY T-CELLS (CD3+/CD5+) WITH SOME IMMATURE PHENOTYPES (CD1a+/CD99+). CD20 HIGHLIGHTS THE B-CELLS IN SCATTERED GERMINAL CENTERS. CD117 IS NEGATIVE. THESE FINDINGS SUPPORT THE DIAGNOSIS.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

** Continued on next page **

ICD-O 3
Thymoma, type A, malignant
8581/3
Site Anterior mediastinum C38.1
9/23/12/14

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #:

Physician:

Service: Thoracic

Date of Report:

Page 2 of 2

Gross Description:

1). The specimen is received fresh for frozen section consultation, labeled " Anterior mediastinal mass, for tissue diagnosis " and consists of a pink tan fibromembranous soft tissue mass measuring 10 x 6 x 4.2 cm. One side is covered with a thin pink membranous tissue. The margins are inked black. Cut surface reveals a well-circumscribed pink tan meaty appearing tumor mass with interspersed white tan fibrous and yellow cheese-like material. A representative section is submitted for frozen section and for permanent. The specimen has been photographed. TPS is taken.

Summary of sections:

FSC -- frozen section control

RS -- representative sections, remaining specimen

Summary of Sections:

Part 1: SP: Anterior mediastinal mass for tissue (fs)

Block	Sect.	Site	PCs
1		FSC	1
12		RS	12

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: ANTERIOR MEDIASTINAL MASS FOR TISSUE (FS): FAVOR THYMOMA

PERMANENT DIAGNOSIS: SAME

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: ANTERIOR MEDIASTINAL MASS FOR TISSUE (FS): FAVOR THYMOMA

PERMANENT DIAGNOSIS: SAME

** End of Report **

Dual/Synchronous Primary	Noted	✓

Source: NCI Genomic Data Commons file 4033e511-ee3b-419f-a175-c039d6041c37 (TCGA-XM-A8R9.5A4ADD81-4577-45D7-81CA-174BC503A870.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).